CPTAC case C3L-01865 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f3068c13-3f95-41eb-95cc-ea69bcea83ad

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive; Country of birth: United States.

Diagnoses (1)
1. Hereditary leiomyomatosis & RCC-associated renal cell carcinoma: ICD-O-3 morphology code: 8311/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 71.9 years (26,260 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,645 days (4.5 years); Progression or recurrence: no; Days to last follow up: 1,645 days (4.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 7.5 cm; Lymph node involvement: Positive; Lymph nodes positive: 5; Lymph nodes tested: 8; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (6 entries)
- Days to follow up: 365 days (1.0 years); Disease response: Tumor Free.
- Days to follow up: 725 days (2.0 years); Disease response: Tumor Free.
- Days to follow up: 1,104 days (3.0 years); Disease response: Tumor Free.
- Days to follow up: 1,411 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,411 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,645 days (4.5 years); Disease response: Tumor Free.

Other clinical attributes
- Weight: 110.68 kg; Height: 160.02 cm; BMI: 43.22.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Cigarettes per day: 20; Tobacco smoking quit year: 1990; Alcohol history: Yes; Alcohol intensity: Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01865-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 217 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01865-21: Section location: Left; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-01865-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 255 mg; Time between excision and freezing: 23 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01865-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
